Somatic mutation profile of tumor specimen 0DMUZC from CCDI case PBCAKS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 22.6 years (8,256 days).
Specimen 0DMUZC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60edb315-f333-46e0-9b5a-2061c8f9e354.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMUX9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/259d1456-5784-4082-824c-93c2757f21c1

The open-access MAF lists 39 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 10, Silent 4, 5'UTR 3, Nonsense Mutation 3, 3'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4398G>T p.W1466C | Missense Mutation (SNP) | VAF 257/528 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54327842, COSV54327957, COSV54334788; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 101/229 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTCH1 | c.2308C>T p.R770* | Nonsense Mutation (SNP) | VAF 275/642 reads (43%) | catalogued as rs766313615, CD054985, COSV59504236; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTCH1 | c.938C>G p.S313* | Nonsense Mutation (SNP) | VAF 239/517 reads (46%) | catalogued as rs1564055259, CM054091; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.1137G>T p.M379I (on ENST00000399959; = p.M380I on NM_001356.5) | Missense Mutation (SNP) | VAF 153/153 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67863682, COSV67864048; called by muse, mutect2, varscan2
- PLEKHM2 | c.2626G>T p.V876F | Missense Mutation (SNP) | VAF 157/351 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1464968857; called by muse, mutect2, varscan2
- SMCO1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 170/565 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.087); catalogued as rs79673145; called by muse, mutect2, varscan2
- TEFM | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 160/342 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs759875480; called by muse, mutect2, varscan2
- TTLL10 | c.1648G>A p.G550S | Missense Mutation (SNP) | VAF 242/509 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs530560103; called by muse, mutect2, varscan2
- ASH2L | c.1493C>A p.T498K | Missense Mutation (SNP) | VAF 116/286 reads (41%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 30/604 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- EPRS1 | c.2542G>C p.A848P | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.633); called by muse, varscan2
- H4C5 | c.282G>T p.Q94H | Missense Mutation (SNP) | VAF 387/810 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- NCOA2 | c.2372_2375del p.M791Tfs*122 | Frame Shift Del (DEL) | VAF 75/184 reads (41%) | called by mutect2, varscan2
- NXT2 | c.154G>T p.A52S (on ENST00000372106 / NM_001242617.2; = p.A107S on NM_018698.5) | Missense Mutation (SNP) | VAF 136/140 reads (97%) | SIFT tolerated (0.44); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SSH2 | c.1928C>G p.S643* | Nonsense Mutation (SNP) | VAF 27/474 reads (6%) | called by muse, mutect2
- STARD5 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 138/327 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- TMEM131L | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 193/502 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- UBASH3B | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 275/600 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WNK3 | c.4175C>T p.T1392I | Missense Mutation (SNP) | VAF 47/260 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IQGAP2 | c.4578T>C p.L1526= | Silent (SNP) | VAF 175/388 reads (45%) | called by muse, varscan2
- KRT26 | c.615C>T p.T205= | Silent (SNP) | VAF 172/405 reads (42%) | catalogued as rs780850839, COSV59416208; called by muse, mutect2, varscan2
- ZCCHC13 | c.345C>T p.C115= | Silent (SNP) | VAF 135/136 reads (99%) | catalogued as COSV59866396, COSV59866580; called by muse, mutect2, varscan2
- ZFP42 | c.48C>T p.G16= | Silent (SNP) | VAF 223/499 reads (45%) | catalogued as COSV100478851; called by muse, mutect2, varscan2
- BTLA | c.-99G>T | 5'UTR (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- CBX3 | c.*28T>A | 3'UTR (SNP) | VAF 22/188 reads (12%) | catalogued as COSV100523016; called by muse, varscan2
- CEP43 | c.301-89T>C | Intron (SNP) | VAF 8/60 reads (13%) | called by muse, varscan2
- CFLAR | c.606+1026T>A | Intron (SNP) | VAF 22/342 reads (6%) | called by muse, mutect2
- DHRS9 | c.-41T>A | 5'UTR (SNP) | VAF 32/340 reads (9%) | called by mutect2, varscan2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 8/35 reads (23%) | called by muse, varscan2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 8/35 reads (23%) | called by muse, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 6/56 reads (11%) | called by muse, varscan2
- NR4A3 | c.*72G>C | 3'UTR (SNP) | VAF 6/57 reads (11%) | called by muse, varscan2
- PCCB | c.373-84G>A | Intron (SNP) | VAF 54/141 reads (38%) | called by muse, mutect2, varscan2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 4/17 reads (24%) | catalogued as COSV55814242; called by muse, mutect2, varscan2
- PSME4 | c.-82C>G | 5'UTR (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- RALGDS | c.2455-9G>A | Intron (SNP) | VAF 68/150 reads (45%) | catalogued as rs376010832; called by muse, mutect2, varscan2
- STAP2 | c.1073-114C>G | Intron (SNP) | VAF 6/39 reads (15%) | catalogued as rs1318630219; called by muse, mutect2
- TRPA1 | c.1195-74T>A | Intron (SNP) | VAF 7/40 reads (18%) | called by muse, varscan2
